Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2W, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2W-01A (Primary Tumor).

Female

Surgery Date:

DIAGNOSIS:

- A. Lymph nodes, hepatoduodenal ligament, lymphadenectomy: Multiple
(4) lymph nodes are negative for tumor.
B. Soft tissue, interductal region, biopsy: Grade 3 (of 4) cholangiocarcinoma.

C. Liver, segments I and V through VIII, resection: Moderately differentiated grade 3 (of 4) cholangiocarcinoma is identified forming a single mass (6.2 x 5.5 x 3.1 cm). The tumor is confined to the hepatic parenchyma. Tumor growth pattern is mass-forming. The hepatic parenchyma resection margin is negative for tumor (minimum tumor free margin, 0.3 cm). Major vessel invasion is absent. Microscopic vessel invasion is present. No regional lymph nodes are identified.

D. Lymph node, periaortic, lymphadenectomy: A single (of 11) lymph node is positive for metastatic cholangiocarcinoma.

ICD-O-3

Cholangiocarcinoma 8160/3

Site, Intrahepatic bile duct C22.1

JP 3/8/14

Source: NCI Genomic Data Commons file 58f101eb-551e-43fe-954c-f4c53a344d60 (TCGA-W5-AA2W.EB47A378-F3DA-4892-8126-99CEE6BFA8EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).